MMRF case MMRF_1364 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1fc3d6db-29e4-4cfa-8746-93d867581d17

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.5 years (20,619 days); ISS stage: I; Days to last known disease status: 268 days; Days to last follow up: 268 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 83 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 172 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 1): M Protein 5.6 g/dL; Immunoglobulin G 86.4 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 1.1 µg/mL; Hemoglobin 7.56 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.81 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.53 mmol/L; Albumin 39 g/L; Total Protein 13 g/dL; Glucose 5.61 mmol/L.
- Day 84 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 46.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.28 mg/dL; Hemoglobin 6.08 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 35 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 22.5 mmol/L; Calcium 2.13 mmol/L; Glucose 6.93 mmol/L.
- Day 174 (ECOG 1): Hemoglobin 7.19 mmol/L; Leukocytes 2.8 ×10⁹/L; Platelets 272 ×10⁹/L.
- Day 268: Hemoglobin 6.26 mmol/L; Leukocytes 5.3 ×10⁹/L; Platelets 77 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.08 mmol/L; Albumin 28 g/L; Total Protein 5.6 g/dL; Glucose 15.1 mmol/L.

Other clinical attributes
- Day -5: Weight: 100 kg; Height: 179 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1364_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1364_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
